Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90Q, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A90Q-01A (Primary Tumor).

ICD-3

Seminoma NOS 9061/3
Site @ Testis NOS C62.9
Q1 3/13/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

Product of right orchiectomy:

- Classic seminoma, measuring 9.8 x 7.7 x 6.8 cm.
- Tumoral infiltration of tunica albuginea and tunica vaginalis.
- Tumoral infiltration of rete testis.
- Cord uninvolved by neoplasia.
- Surgical margins uninvolved by neoplasia.
- Epididymis uninvolved by neoplasia.
- Presence of intratubular germ cell neoplasia.

Reviewed: Initials	AW	

Source: NCI Genomic Data Commons file 140eb9eb-9b01-4931-be9d-b1cb4680cd1c (TCGA-YU-A90Q.D6927A77-BDB7-4798-9777-F61542481101.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).